Surgical pathology report (de-identified scan), TCGA case TCGA-BA-A4IH, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site UNC, specimen TCGA-BA-A4IH-01A (Primary Tumor).

[page 1 of 4]
SURGICAL PATHOLOGY REVISED REPORT

Case Number :

Diagnosis:

A: Deep margin, excision
- Negative for carcinoma

B: Pharynx, right, pharyngectomy

Tumor histologic type: Basaloid squamous cell carcinoma

Histologic grade: poorly differentiated 1CD-0-3

Tumor focality: Unifocal

carcinoma, squamous cell, basaloid 8083/3

Tumor size: 3.1 x 2.2 x 1.9 cm

Site: oropharynx, NOS C10.9

Extent of invasion:

- Tonsil invasion: present
- Skeletal muscle invasion: present, focal (B10)
- Venous invasion: present (B2)
- Lymphatic invasion: not identified
- Perineural invasion: Not identified
- Bone invasion: none for evaluation

*hw
10/3/12*

HR HPV: outside report: PCR screening positive for HPV16.

- P16 by IHC: positive
- HR HPV by ISH: positive

Surgical margins:

- Deep margin focally positive (B3), possibly superseded by specimen A
- 9-12 o' clock (presumed superior-lateral) margin focally positive (B3)
- Other margins not involved:
- Carcinoma extends to <1 mm from the 6 o' clock (inferior) margin (B2)
- Carcinoma extends to <1 mm from 12 to 3 o' clock (presumed superior-medial) margin (B4)
- Carcinoma extends to 1 mm from 3 to 6 o' clock (presumed inferior-medial) margin (B10)
- Carcinoma extends to 8 mm from 6 to 9 o' clock (presumed inferior-lateral) margin (B9)

Lymph nodes: See specimens C, D, and E

[page 2 of 4]
AJCC Pathologic Stage (Tonsil, oropharynx): pT2 pN2b pMx (stage revised, see Amendment Comment below)

NOTE: This pathologic stage assessment is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

C: Lymph nodes, right cervical level 4, regional dissection
- No metastatic carcinoma identified (0/12)

D: Lymph nodes, right cervical level 2, regional dissection
- Metastatic basaloid squamous carcinoma (1/12), 1.5 cm diameter, without extracapsular extension

E: Lymph nodes, right cervical level 3, regional dissection
- Metastatic basaloid squamous carcinoma (1/15), 0.5 cm diameter, without intact capsule for evaluation

Comment:

Amendment Comment:

Following case finalization, it was brought to our attention that there are different node staging systems for different pharyngeal sites. For oropharynx, metastasis to multiple ipsilateral nodes <6 cm in diameter is staged as N2b, rather than as N1. The AJCC pathologic stage is revised, as above.

Intraoperative Consult Diagnosis:
Frozen section was requested by Dr. in

FSA1: Deep margin, biopsy
- No tumor seen

Drs.

Frozen Section Pathologist:, MD, PhD

Clinical History:

-year-old male with likely HPV+ tonsillar squamous cell carcinoma.

Gross Description:

Specimen A is received is fresh for frozen section in one

[page 3 of 4]
appropriately labeled container additionally labeled "deep margin, biopsy." It holds three brown/tan soft tissue fragments, 1.5 x 1.0 x 0.4 cm in aggregate which are serially cauterized. The entire specimen is submitted in block FSA1,

Specimen B is additionally labeled "right pharyngectomy, long stitch = soft palate, short stitch = tongue base". The container holds a single irregularly shaped pink/tan soft tissue fragment with a single long stitch attached. A short stitch is present detached inside the container. The specimen measures 5.4 x 3 cm with a maximum thickness of 2 cm, and has an apex at the long stitch and a broad base at the opposite end. The mucosal surface shows a white/tan firm irregular mass which on sectioning appears invasive and has a slightly mucoid cut surface. The mass measures 2.2 x 3.1 cm across the surface of the specimen by 1.9 cm in depth. The deep margin is irregular, cauterized fibromuscular tissue. The peripheral margin closest to the long stitch is inked green and the peripheral margin of the opposite half is inked blue. The deep margin is inked black. The mass focally abuts the black inked deep margin and comes within 1 mm of both blue and green inked peripheral margins. It is 0.6 cm from the margin marked by the long stitch (soft palate margin) and appears to abut the opposite end of the specimen. The long stitch is designated 12 o'clock. The tumor is slightly off center in the 12-3-6 o' clock half of the specimen.

Block Summary:

- B1 - Perpendicular sections to the soft palate margin (long stitch)
- B2 - Perpendicular sections to the 6 o' clock end (broad base)
- B3 - Perpendicular sections to 9 to 12 o' clock
- B4 - Perpendicular sections to 12 to 3 o' clock
- B5-B6 - Perpendicular sections to 6 to 9 o' clock
- B7-B8 - Perpendicular sections to 3 to 6 o' clock
- B9 - Perpendicular to 6 to 9 o' clock
- B10 - Perpendicular to 3 to 6 o' clock (B9-B10 single cross sections through tumor bisected)

Specimen C is additionally labeled "right level 4" and holds a 5.5 x 3 x 0.7 cm fragment of lobulated fibroadipose tissue. The specimen is palpated for lymph nodes.

Block Summary:

- C1-C3 - Multiple lymph node candidates each cassette
- C4-C5 - Additional fat for non-palpable lymph nodes

Specimen D is additionally labeled "right level 2" and holds a 4.5 x 2 x 1 cm fibroadipose soft tissue fragment. The specimen

[page 4 of 4]
is dissected for lymph nodes.

Block Summary:

D1-D2 - One 2.5 cm lymph node, bisected

D3 - One lymph node candidate, bisected

D4 - One lymph node candidate

D5-D7 - Multiple lymph node candidates, each cassette,

Specimen E is additionally labeled "right level 3" and holds a 4.5 x 3 x 1 cm fibroadipose soft tissue fragment. The specimen is dissected for lymph nodes.

Block Summary:

E1-E3 - Multiple lymph nodes, each cassette

E4-E7 - Additional soft tissue for lymph nodes

Tissue remains in formalin.

lw
10/3/12

Source: NCI Genomic Data Commons file 4b7844db-a6f7-45cb-8b36-c7feaeb1b8c4 (TCGA-BA-A4IH.C39082CF-AA08-43F8-87F2-B632A29506FF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).